Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7432, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7432-01A (Primary Tumor).

[page 1 of 2]
SUPPLEMENTAL REPORT

DIAGNOSIS:

- (F) LEFT HEMIMANDIBLE:
Decalcified sections of mandible underlying the carcinoma are negative for tumor.

DIAGNOSIS

- (A) UPPER AND MID JUGULAR LYMPH NODES:
Sixteen lymph nodes, no evidence of metastatic disease.
- (B) LEFT MANDIBULAR NERVE:
Peripheral nerve, no evidence of carcinoma.
- (C) TONGUE MARGIN:
Squamous mucosa, skeletal muscle and salivary gland, no evidence of carcinoma.
- (D) BUCCAL MARGIN:
Squamous mucosa, skeletal muscle and salivary tissue, no evidence of carcinoma.
- (E) ANTERIOR TONSILLAR PILLAR MARGIN:
Squamous mucosa and salivary gland tissue, no evidence of carcinoma.
- (F) TUMOR WITH SUBMANDIBULAR TRIANGLE AND LEFT HEMIMANDIBLE:
INVASIVE, WELL DIFFERENTIATED SQUAMOUS CARCINOMA, 3.0 X 3.0 X 2.5 CM.
PERINEURAL INVASION IDENTIFIED.
No lymphovascular invasion identified.
Four submandibular lymph nodes, no evidence of metastatic disease.
Tonsil with reactive follicular hyperplasia.

[page 2 of 2]
GROSS DESCRIPTION

(A) UPPER AND MID JUGULAR NODES, HEMOSTAT SUPERIOR - A fragment of adipose tissue (5.0 x 2.0 x 1.0 cm) containing sixteen lymph nodes ranging in size from 0.2 to 1.8 cm. Lymph nodes are serially dissected from superior to inferior and submitted in A1-A12, in order.

SECTION CODE: A1-A9, A12, single lymph node in each cassette; A10, three small lymph nodes; A11, three small lymph nodes.

*FS/DX: PERIPHERAL NERVE, NO TUMOR PRESENT.

(B) LEFT MANDIBULAR NERVE, HEMOSTAT PROXIMAL - A strip of nerve tissue (3.0 x 0.3 x 0.3 cm) with hemostat designating proximal margin. The distal margin is inked black and is taken for frozen section en face with the adjacent nerve in longitudinal. The proximal margin is inked red and the remaining tissue is totally submitted in B2.

(C) TONGUE MARGIN, HEMOSTAT ANTERIOR, NEW MARGIN INKED - An irregular strip of tongue tissue (5.0 x 1.5 x 1.0 cm) with hemostat designating anterior. The new margin is previously inked by surgeon.

INK CODE: Anterior-red, posterior-yellow, deep-black, previously inked.

SECTION CODE: C1-C4, new margin en face for frozen section anterior to posterior; C5-C6, random mucosal section, permanent.

*FS/DX: NO TUMOR PRESENT.

(D) BUCCAL MUCOSAL MARGIN, HEMOSTAT ANTERIOR - A strip of red-tan mucosa (4.0 x 1.0 x 1.0 cm) with hemostat designating anterior.

INK CODE: Anterior-red, posterior-yellow, deep-black.

SECTION CODE: D1-D3 margin, en face, anterior to posterior, for frozen section.

*FS/DX: NO TUMOR PRESENT.

(E) ANTERIOR TONSILLAR PILLAR MARGIN, HEMOSTAT ANTERIOR - A strip of red-tan mucosa (2.5 x 0.5 x 0.5 cm) with a hemostat designating anterior.

INK CODE: Anterior-red, posterior-yellow, deep-black.

SECTION CODE: E1, E2, margin, en face for frozen section, anterior to posterior.

*FS/DX: NO TUMOR PRESENT.

(F) TUMOR HEMIMANDIBLE AND SUBMANDIBULAR TRIANGLE - Tumor and soft tissue (6.0 x 3.0 x 3.0 cm) with contiguous submandibular triangle (5.0 x 4.0 x 1.0 cm and portion of left hemimandible (composite hemimandibulectomy) (7.0 x 3.0 x 1.0 cm). Overlying mucosa on the soft tissue measures 5.0 x 1.0 cm.

A crescent shape centrally ulcerated tumor is present on the mucosal surface, it measures 3.0 x 3.0 x 2.5 cm and has pushing borders, but there is no definite invasion into the submandibular triangle. The tumor is white-gray with a vague lobulated appearance. The margins have been previously examined by frozen section.

Five possible lymph nodes ranging in size from 0.5 to 0.8 cm are dissected. The portion of mandible is grossly unremarkable. The bone is pending decalcification.

SECTION CODE: F1-F4, tumor; F5, tumor and contiguous salivary gland tissue; F6-F9, single lymph node in each cassette; F10, one possible lymph node.

SNOMED CODES

M-80703 T-51600

Source: NCI Genomic Data Commons file 7e5544fb-33b2-49c3-9c37-f867f684b3d3 (TCGA-CV-7432.730F0533-0064-41E8-8EBA-5DE16CDA3997.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).